HCMI case HCM-BROD-0761-C71 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/04ba3395-30c3-4e6e-964a-fe9f82dd8a97

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1956; Vital status: Dead; Days to death: 709 days (1.9 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 62.4 years (22,788 days); WHO CNS grade: Grade IV; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Prior treatment: No.
   Pathology details: Necrosis present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 2 days.
   Treatment given: Treatment type: Radiation, 2D Conventional; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 19 days; Days to treatment end: 68 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 19 days; Days to treatment end: 266 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 404 days (1.1 years); Days to treatment end: 445 days (1.2 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Regorafenib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 455 days (1.2 years); Days to treatment end: 500 days (1.4 years).
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Bevacizumab; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 509 days (1.4 years); Days to treatment end: 624 days (1.7 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease.

Follow-up (3 entries)
- Days to follow up: 0 days; Karnofsky performance status: 80.
- Days to follow up: 709 days (1.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 15.

Molecular and laboratory tests
- IDH1 (IHC): Negative; Amino-acid change: R132H.
- IDH1 / IDH2 (Targeted Sequencing): Negative.
- MGMT methylation: Positive.
- Test: Negative; Mismatch repair mutation: Yes.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 169 cm; BMI: 26.6.

Exposures
- Tobacco smoking status: Current Reformed Smoker for > 15 yrs.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Glioblastoma.

Biospecimens (2 samples)
- Sample HCM-BROD-0761-C71-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0761-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Mixed Adherent Suspension; Preservation method: Frozen; Passage count: 7.
